Somatic mutation profile of cancer-model specimen HCM-CSHL-0182-C25-85A (3D Organoid; aliquot HCM-CSHL-0182-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0182-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 74.6 years (27,264 days).
Specimen HCM-CSHL-0182-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3abd0b1e-9fca-4704-8a22-ccabfacbcd9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0182-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0182-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce25d259-4556-4b40-8df5-c221c2d0190b

The open-access MAF lists 84 somatic variants for this specimen: 49 protein-altering or splice-affecting, 20 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 20, Intron 7, 5'UTR 4, RNA 2, Frame Shift Del 2, 5'Flank 1, Splice Region 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 264/428 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 345/346 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS7 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 81/164 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1334037274, COSV66309951; called by muse, mutect2, varscan2
- ADGRG4 | c.3869G>T p.G1290V | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV54954574; called by muse, mutect2, varscan2
- AGBL4 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs755308164; called by muse, mutect2, varscan2
- AKAP9 | c.11683G>A p.D3895N (on ENST00000359028; = p.D3871N on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 162/498 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as rs376870775; called by muse, varscan2
- ALPP | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 181/617 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs755952363, COSV67397383; called by muse, mutect2, varscan2
- ATXN7L1 | c.1705G>T p.V569L | Missense Mutation (SNP) | VAF 116/166 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as COSV66300240; called by muse, mutect2, varscan2
- CDH10 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 74/285 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52578279; called by muse, mutect2, varscan2
- CHRNB2 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 118/524 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.066); catalogued as rs778714852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FHL1 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 164/360 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.264); catalogued as COSV61780230, COSV61780414; called by muse, mutect2, varscan2
- FLNC | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 261/837 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776362922, COSV57965274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HK2 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 249/573 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1224700820; called by muse, mutect2, varscan2
- IQSEC3 | c.371C>G p.P124R | Missense Mutation (SNP) | VAF 163/944 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); catalogued as rs781892955; called by muse, mutect2, varscan2
- KL | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.44); catalogued as rs757477654; called by muse, mutect2, varscan2
- KRT33B | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 77/258 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as rs746738328; called by muse, mutect2, varscan2
- MDGA1 | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762711500, COSV51798335; called by muse, mutect2, varscan2
- OGDHL | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 115/800 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs369109768, COSV65105105; called by muse, mutect2, varscan2
- PLEKHG4B | c.13C>T p.R5W (on ENST00000283426; = p.R361W on NM_052909.5) | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1039069776, COSV52056311; called by muse, mutect2, varscan2
- ROBO3 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010020965; called by muse, mutect2, varscan2
- SERINC2 | c.783C>T p.D261= (on ENST00000373709 / NM_178865.5; = p.D265= on NM_018565.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 97/200 reads (49%) | catalogued as rs558799797, COSV65490899; called by muse, mutect2, varscan2
- SPATA31D1 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 214/760 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs765399068, COSV61196397; called by muse, mutect2, varscan2
- SPATC1 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 150/448 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs527279030, COSV66298471; called by muse, mutect2, varscan2
- STK3 | c.610A>G p.I204V | Missense Mutation (SNP) | VAF 79/309 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.557); catalogued as rs766490046; called by muse, mutect2, varscan2
- SYNE1 | c.13553G>A p.R4518H (on ENST00000367255 / NM_182961.4; = p.R4447H on NM_033071.3) | Missense Mutation (SNP) | VAF 159/292 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148248006, COSV54917149; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF596 | c.674G>C p.C225S | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490217015; called by muse, mutect2, varscan2
- CDKN2A | c.310_311insGCGGT p.L104Rfs*44 | Frame Shift Ins (INS) | VAF 604/634 reads (95%) | called by mutect2, varscan2
- CSMD2 | c.3604C>A p.H1202N | Missense Mutation (SNP) | VAF 80/168 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EFTUD2 | c.1720del p.A574Lfs*7 | Frame Shift Del (DEL) | VAF 125/248 reads (50%) | called by mutect2, pindel, varscan2
- HOXB3 | c.705G>A p.W235* | Nonsense Mutation (SNP) | VAF 127/389 reads (33%) | called by muse, mutect2, varscan2
- HSF1 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- KRT80 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 144/499 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, varscan2
- KRT80 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, varscan2
- MICU3 | c.1359A>G p.I453M | Missense Mutation (SNP) | VAF 50/51 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MYO1H | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL7 | c.1691A>G p.Y564C | Missense Mutation (SNP) | VAF 128/385 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PLEKHA1 | c.785C>T p.T262I | Missense Mutation (SNP) | VAF 25/294 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ROBO1 | c.3200C>T p.S1067L | Missense Mutation (SNP) | VAF 140/272 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- RPL3L | c.164A>T p.H55L | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC47A1 | c.937A>G p.S313G | Missense Mutation (SNP) | VAF 108/215 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SPEF2 | c.5425G>T p.D1809Y | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TNFRSF6B | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 276/435 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TSPAN18 | c.444C>G p.C148W | Missense Mutation (SNP) | VAF 46/470 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC93B1 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASF2 | c.576C>A p.N192K | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- ZNF134 | c.414G>C p.Q138H | Missense Mutation (SNP) | VAF 136/196 reads (69%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF208 | c.3489T>G p.H1163Q | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ZNF528 | c.64T>A p.W22R | Missense Mutation (SNP) | VAF 301/442 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF610 | c.271del p.I91* | Frame Shift Del (DEL) | VAF 67/272 reads (25%) | called by mutect2, pindel, varscan2
- ADD2 | c.261G>A p.L87= | Silent (SNP) | VAF 99/227 reads (44%) | catalogued as rs144778680; called by muse, mutect2, varscan2
- CDH10 | c.1773C>T p.S591= | Silent (SNP) | VAF 195/600 reads (33%) | called by muse, mutect2, varscan2
- CEP135 | c.2991G>A p.S997= | Silent (SNP) | VAF 59/123 reads (48%) | catalogued as rs200864117; called by muse, mutect2, varscan2
- CGB1 | c.138C>T p.T46= | Silent (SNP) | VAF 362/876 reads (41%) | catalogued as rs765381688; called by muse, varscan2
- CHGA | c.294C>T p.S98= | Silent (SNP) | VAF 110/256 reads (43%) | catalogued as rs150929444, COSV99381139; called by muse, mutect2, varscan2
- CLIC5 | c.315C>A p.I105= | Silent (SNP) | VAF 346/855 reads (40%) | called by muse, mutect2, varscan2
- DGKZ | c.39C>T p.S13= | Silent (SNP) | VAF 59/569 reads (10%) | catalogued as rs1249768235; called by muse, mutect2, varscan2
- FMN1 | c.1734G>A p.K578= | Silent (SNP) | VAF 123/253 reads (49%) | called by muse, mutect2, varscan2
- FXR1 | c.1083A>T p.V361= | Silent (SNP) | VAF 111/248 reads (45%) | called by muse, mutect2, varscan2
- KIAA1217 | c.570G>A p.Q190= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as rs745540023; called by muse, mutect2
- MECOM | c.687G>C p.T229= (on ENST00000468789 / NM_001105078.4; = p.T417= on NM_004991.4) | Silent (SNP) | VAF 142/297 reads (48%) | called by muse, mutect2, varscan2
- NAV1 | c.1515T>G p.P505= | Silent (SNP) | VAF 233/420 reads (55%) | called by muse, mutect2, varscan2
- PHACTR3 | c.12G>A p.S4= | Silent (SNP) | VAF 45/114 reads (39%) | called by muse, mutect2, varscan2
- POLA1 | c.2391C>T p.Y797= | Silent (SNP) | VAF 116/116 reads (100%) | catalogued as rs201734540; called by muse, mutect2, varscan2
- POM121L12 | c.282C>T p.S94= | Silent (SNP) | VAF 195/295 reads (66%) | catalogued as rs1038709836, COSV68692409; called by muse, mutect2, varscan2
- PRKG1 | c.810G>A p.G270= | Silent (SNP) | VAF 127/342 reads (37%) | called by muse, mutect2, varscan2
- RASAL3 | c.894C>T p.N298= | Silent (SNP) | VAF 155/377 reads (41%) | called by muse, mutect2, varscan2
- TRIM58 | c.174G>A p.P58= | Silent (SNP) | VAF 59/143 reads (41%) | called by muse, mutect2, varscan2
- USP43 | c.1026G>A p.E342= | Silent (SNP) | VAF 63/141 reads (45%) | catalogued as rs772909872; called by muse, mutect2, varscan2
- XG | c.33G>A p.A11= | Silent (SNP) | VAF 54/54 reads (100%) | catalogued as rs144280532; called by muse, mutect2, varscan2
- ARHGAP39 | c.2522-3567_2522-3565del | Intron (DEL) | VAF 52/258 reads (20%) | catalogued as rs776371042; called by pindel, varscan2
- CAPRIN2 | c.2148+1672A>G | Intron (SNP) | VAF 89/293 reads (30%) | called by muse, mutect2, varscan2
- CRYGD | c.-12G>A | 5'UTR (SNP) | VAF 96/207 reads (46%) | catalogued as rs778404764; called by muse, mutect2, varscan2
- FBXL5 | c.301-699G>A | Intron (SNP) | VAF 22/118 reads (19%) | catalogued as rs746892658; called by muse, mutect2, varscan2
- GCNT2 | c.926-35311C>T | Intron (SNP) | VAF 107/203 reads (53%) | called by muse, mutect2, varscan2
- GPR157 | c.-31C>T | 5'UTR (SNP) | VAF 17/37 reads (46%) | called by muse, mutect2, varscan2
- HEXA | c.1147-43C>T | Intron (SNP) | VAF 34/214 reads (16%) | called by muse, mutect2, varscan2
- LRRC75B | chr22:24583699 G>T | 3'Flank (SNP) | VAF 122/122 reads (100%) | called by muse, mutect2, varscan2
- PNLDC1 | c.-124G>A | 5'UTR (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- PRDM16 | chr1:3067555 G>A | 5'Flank (SNP) | VAF 93/187 reads (50%) | called by muse, mutect2, varscan2
- RPL37A | c.-21T>C | 5'UTR (SNP) | VAF 91/188 reads (48%) | catalogued as rs781242814; called by muse, mutect2, varscan2
- SEC14L1 | c.2042+68del | Intron (DEL) | VAF 104/143 reads (73%) | called by mutect2, pindel, varscan2
- SEPTIN9 | c.722-36603C>T | Intron (SNP) | VAF 3/25 reads (12%) | catalogued as rs1440997083, COSV61204726; called by muse, mutect2
- SSPOP | n.13219C>T | RNA (SNP) | VAF 198/631 reads (31%) | called by muse, mutect2, varscan2
- ZNF812P | n.1387A>C | RNA (SNP) | VAF 86/185 reads (46%) | called by muse, mutect2, varscan2
